Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A437, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A437-01A (Primary Tumor).

Procurement Date: Laterality: Thyroid gland, right lobe (hemithyroidectomy):

- Papillary thyroid carcinoma (1.5 x 1.5 x 1.3 cm).
- No angiolymphatic invasion is identified.
- No extension of the carcinoma beyond the thyroid gland is identified.
- No involvement of the surgical margin by the carcinoma is identified.
- One associated benign parathyroid gland.

Path Report: Thyroid gland, right lobe (hemithyroidectomy):

- Papillary thyroid carcinoma (1.5 x 1.5 x 1.3 cm).
- No angiolymphatic invasion is identified.
- No extension of the carcinoma beyond the thyroid gland is identified.
- No involvement of the surgical margin by the carcinoma is identified.
- One associated benign parathyroid gland.
- Tumor focality: unifocal
- Tumor laterality: right

ICD-O-3

carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS

C73.9

8-3-12
CO

Cont

hw 11/26/12

Source: NCI Genomic Data Commons file 1551ce35-1f93-4c07-903b-465fb4613755 (TCGA-E8-A437.8A3ABA86-6ED1-4CD8-B8DF-5A39D8C7CB34.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).